Somatic mutation profile of tumor specimen MMRF_1252_1_BM_CD138pos (aliquot MMRF_1252_1_BM_CD138pos_T2_TSE61_L00074) from MMRF case MMRF_1252, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.3 years (28,229 days).
Specimen MMRF_1252_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51d3ddfe-9465-48f7-894a-2abdabd042c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1252_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1252_1_PB_Whole_C1_TSE61_L00077; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1d5564-7ee9-4fe5-b4a4-6f560aecbc8b

The open-access MAF lists 108 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 30, Silent 15, 5'UTR 7, Intron 4, Frame Shift Del 4, RNA 3, 5'Flank 3, Nonsense Mutation 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 51/106 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs749482988, COSV53052132; called by muse, mutect2, varscan2
- ADAMTS14 | c.3339del p.F1114Sfs*96 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs751207045, COSV100941549; called by mutect2, pindel
- BMP6 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs1319282365, COSV51672259; called by muse, mutect2, varscan2
- COPE | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.116); catalogued as COSV53229729; called by muse, mutect2, varscan2
- DLEU7 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1161954740; called by muse, mutect2, varscan2
- DLG4 | c.1154C>T p.T385M (on ENST00000399506 / NM_001321075.3; = p.T428M on NM_001365.4) | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1385958753; called by muse, mutect2, varscan2
- DPH1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs767417481, COSV53985426; called by muse, mutect2, varscan2
- EZH2 | c.455del p.N152Ifs*15 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as COSV100235433; called by mutect2, pindel, varscan2
- H4-16 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100797682, COSV63762108; called by muse, mutect2, varscan2
- KCNA5 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 161/293 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751395749, COSV99363883; called by muse, mutect2, varscan2
- KCNK16 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100949367; called by muse, mutect2, varscan2
- KLF17 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs768956475, COSV64856162; called by muse, mutect2, varscan2
- KRTAP25-1 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV101342662; called by muse, mutect2, varscan2
- LAMA1 | c.2747T>C p.L916P | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs769368993; called by muse, mutect2, varscan2
- NCKAP5 | c.1061C>G p.T354R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747843825, COSV58441127; called by muse, mutect2, varscan2
- OR4A5 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV60521623; called by muse, mutect2, varscan2
- SLC23A1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs369192547; called by muse, mutect2, varscan2
- SORCS3 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs141177706, COSV63801911; called by muse, mutect2, varscan2
- ZNF703 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs1245091054; called by muse, mutect2, varscan2
- ABCB4 | c.1912C>A p.Q638K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP002512.3 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BLMH | c.1310T>C p.L437S | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- DAAM2 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- EYS | c.6015del p.K2005Nfs*34 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- FBN2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GLB1L3 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAI1 | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIPK4 | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF10 | c.2286A>T p.K762N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- JAK3 | c.2885A>G p.H962R | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- KCNT2 | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MAP2 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAALAD2 | c.1496T>A p.L499* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- OR6C68 | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OR6C76 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OSBPL6 | c.1911C>A p.C637* | Nonsense Mutation (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- SETBP1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SHOX2 | c.851T>A p.L284Q (on ENST00000441443 / NM_006884.3; = p.L308Q on NM_003030.4) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRD5A1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TENM4 | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRAF3 | c.121del p.E41Kfs*4 | Frame Shift Del (DEL) | VAF 46/60 reads (77%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2858C>G p.A953G | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CDHR2 | c.3693C>T p.G1231= | Silent (SNP) | VAF 194/402 reads (48%) | called by muse, mutect2, varscan2
- CYP2J2 | c.447T>G p.G149= | Silent (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- DDX60L | c.4620T>A p.P1540= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- FOCAD | c.5382A>T p.V1794= | Silent (SNP) | VAF 38/41 reads (93%) | called by muse, mutect2, varscan2
- IGF1R | c.2559G>A p.P853= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs756094289; called by muse, mutect2, varscan2
- IL12A | c.180C>T p.P60= | Silent (SNP) | VAF 119/253 reads (47%) | catalogued as rs540351202, COSV59758958; called by muse, mutect2, varscan2
- NKD2 | c.267C>T p.D89= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as rs750111447, COSV56891820; called by muse, mutect2, varscan2
- NLGN4X | c.1164C>T p.D388= | Silent (SNP) | VAF 54/61 reads (89%) | catalogued as rs372880465; called by muse, mutect2, varscan2
- OR3A2 | c.183G>A p.E61= | Silent (SNP) | VAF 90/293 reads (31%) | catalogued as rs998303067; called by muse, mutect2, varscan2
- PLCL2 | c.1362C>T p.S454= (on ENST00000615277 / NM_001144382.2; = p.S328= on NM_015184.5) | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs776884102; called by muse, mutect2, varscan2
- PON1 | c.945T>G p.P315= | Silent (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- RASD2 | c.540C>T p.D180= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as rs373368041; called by muse, mutect2, varscan2
- RSPH14 | c.771C>T p.F257= | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as rs530778842, COSV53272080; called by muse, mutect2, varscan2
- TBX2 | c.966C>T p.A322= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as rs1021770653; called by muse, mutect2, varscan2
- TDRD6 | c.75C>T p.P25= | Silent (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- AMBP | c.-49T>C | 5'UTR (SNP) | VAF 91/195 reads (47%) | called by muse, mutect2, varscan2
- CDH13 | c.*1007T>G | 3'UTR (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- CREBBP | c.*1012del | 3'UTR (DEL) | VAF 46/115 reads (40%) | catalogued as COSV99271055; called by mutect2, pindel, varscan2
- CYB5R4 | c.*413A>C | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- DGKB | c.*1899A>C | 3'UTR (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:214414 G>T | 5'Flank (SNP) | VAF 19/21 reads (90%) | called by muse, mutect2, varscan2
- FAM107A | c.*1381C>T | 3'UTR (SNP) | VAF 27/58 reads (47%) | catalogued as rs1238109109; called by muse, mutect2, varscan2
- FBXL20 | c.-156G>A | 5'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- FOCAD | c.*65T>G | 3'UTR (SNP) | VAF 34/37 reads (92%) | called by muse, varscan2
- FOCAD | c.*123A>G | 3'UTR (SNP) | VAF 27/27 reads (100%) | called by muse, varscan2
- GABRA3 | c.*156A>C | 3'UTR (SNP) | VAF 38/42 reads (90%) | called by muse, mutect2, varscan2
- GUSBP1 | n.2337del | RNA (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- GVINP1 | n.2355C>T | RNA (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- HMGB3 | c.*2525T>A | 3'UTR (SNP) | VAF 60/62 reads (97%) | called by muse, mutect2, varscan2
- HSPA2 | chr14:64533039 A>G | 5'Flank (SNP) | VAF 88/92 reads (96%) | catalogued as rs917392369; called by muse, mutect2, varscan2
- IGF2BP1 | c.*4444_*4447del | 3'UTR (DEL) | VAF 45/91 reads (49%) | called by mutect2, pindel, varscan2
- ITGA2B | c.*30G>A | 3'UTR (SNP) | VAF 45/111 reads (41%) | catalogued as rs867803957; called by muse, mutect2, varscan2
- KCNIP4 | c.61+251194A>C | Intron (SNP) | VAF 9/24 reads (38%) | catalogued as COSV66171470; called by mutect2, varscan2
- KCNJ2 | c.*2840T>C | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- KCNV1 | c.-209C>G | 5'UTR (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- KCTD7 | c.*3457T>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, varscan2
- KCTD7 | c.*3540T>G | 3'UTR (SNP) | VAF 63/137 reads (46%) | called by muse, varscan2
- KSR1 | c.1510+509T>G | Intron (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- LRCH1 | chr13:46743667 G>T | 3'Flank (SNP) | VAF 27/30 reads (90%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.446G>T | RNA (SNP) | VAF 84/178 reads (47%) | called by muse, mutect2, varscan2
- MYO3B | c.*154A>G | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- NPR3 | c.*2575T>C | 3'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- NRXN1 | c.-571G>A | 5'UTR (SNP) | VAF 61/132 reads (46%) | catalogued as rs750739390, COSV68052786; called by muse, mutect2, varscan2
- OLFM1 | c.*30G>A | 3'UTR (SNP) | VAF 99/222 reads (45%) | catalogued as rs570244203; called by muse, mutect2, varscan2
- OTUD4 | c.159+140T>C | Intron (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- OXR1 | chr8:106752607 A>C | 3'Flank (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- PAK5 | c.*150A>G | 3'UTR (SNP) | VAF 81/81 reads (100%) | catalogued as rs929730220; called by muse, mutect2, varscan2
- PLPPR1 | c.*198T>C | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- PLXNB2 | c.*259C>T | 3'UTR (SNP) | VAF 61/135 reads (45%) | catalogued as rs768379825; called by muse, mutect2, varscan2
- POU3F1 | c.*632A>C | 3'UTR (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*7018T>C | 3'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- QKI | c.935-1394C>T | Intron (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- RAB6A | c.*1745T>G | 3'UTR (SNP) | VAF 116/250 reads (46%) | called by muse, mutect2, varscan2
- RALB | c.-62C>T | 5'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2
- RGS7BP | c.*59C>A | 3'UTR (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- SBSPON | c.*2544T>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- SMG1P5 | chr16:30335170 G>A | 5'Flank (SNP) | VAF 35/73 reads (48%) | catalogued as rs1021123007; called by muse, mutect2, varscan2
- ST8SIA2 | c.*1520G>T | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- TNKS | c.*4557T>C | 3'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- TRIM26 | c.*462A>G | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- TSPAN17 | c.-188C>A | 5'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- USH2A | c.*1324G>A | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- USP19 | c.-157T>C | 5'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- YPEL2 | c.*2675G>A | 3'UTR (SNP) | VAF 6/11 reads (55%) | catalogued as rs188002479; called by muse, varscan2
